Gene-level copy-number profile of specimen HCM-CSHL-0065-C20-85A from HCMI case HCM-CSHL-0065-C20, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 63.3 years (23,111 days).
Specimen HCM-CSHL-0065-C20-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 2ab6129d-b4c2-4390-bfd2-3593b34430f3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0065-C20-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,738 have no estimate.
https://portal.gdc.cancer.gov/files/1067b17d-48d7-4ac0-9b43-1a1e7968f051

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 827; copy number 2: 8,353; copy number 3: 28,857; copy number 4: 16,501; copy number 5: 527; copy number 6: 2,460; copy number 7: 1,355; copy number 8: 5.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,360 genes in 73 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:38,382,364–38,560,939, 8 genes, copy number 7: AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1.
- chr8:38,988,808–39,105,445, 3 genes, copy number 7: TM2D2, ADAM9, SNORD38D.
- chr8:46,028,804–47,736,306, 34 genes, copy number 7: AC118650.1, HSPA8P13, ASNSP1, AC104576.1, ASNSP4, AC021451.1, TRIM60P15, LINC00293, MTND2P38, MTND1P7, RNU6-656P, MTCYBP20, MTND6P20, AC091163.3, AC091163.1, AC091163.2, MAPK6P4, RN7SKP32, AC120036.1, AC120036.5, RNU6-819P, RPL10AP2, NDUFA5P12, AC120036.3, AC120036.4, ATP6V1G1P2, AC120036.2, IGLV8OR8-1, SPIDR, AC024451.2, AC024451.4, AC024451.1, AC024451.3, RNU6-665P.
- chr8:47,960,185–49,352,844, 24 genes, copy number 7: MCM4, RNU6-519P, UBE2V2, AC104989.1, IDI1P2, RNU6-295P, RNA5SP531, RPL29P19, AC041040.1, AC026904.1, AC026904.2, AC022915.2, LINC02599, LINC02847, AC022915.1, AC022915.3, EFCAB1, AC013701.1, SNAI2, AC044893.2, PPDPFL, AC044893.1, RN7SKP294, RFPL4AP7.
- chr8:49,909,789–50,796,692, 3 genes, copy number 7 (within-gene range 6–7): SNTG1, AC090539.1, AC090539.2.
- chr8:51,319,577–51,809,445, 3 genes, copy number 7 (within-gene range 6–7): PXDNL, BRIX1P1, BTF3P1.
- chr8:55,102,028–55,542,054, 5 genes, copy number 7 (within-gene range 6–7): XKR4, AC022679.2, AC022679.1, SBF1P1, AC090200.1.
- chr8:56,373,064–56,776,874, 9 genes, copy number 7: SDR16C6P, PENK, AC012349.1, SEPTIN10P1, LINC00968, AC013644.1, RPL37P6, AC009597.1, AC009597.2.
- chr8:59,561,324–60,142,142, 7 genes, copy number 7: AC087664.1, AC087664.2, AC107934.1, AC107934.2, AC022709.1, AC021393.1, SLC2A13P1.
- chr8:61,057,158–61,501,645, 3 genes, copy number 7 (within-gene range 6–7): CLVS1, NPM1P6, AC023866.2.
- chr8:64,587,763–64,973,848, 5 genes, copy number 7: CYP7B1, AC104232.2, AC104232.3, AC104232.1, AC087808.1.
- chr8:65,161,145–65,771,261, 8 genes, copy number 7 (within-gene range 6–7): LINC00251, PPIAP86, LINC01299, AC100814.1, Y_RNA, ARMC1, MTFR1, AC055822.1.
- chr8:66,021,553–66,518,524, 14 genes, copy number 7: DNAJC5B, AC084082.1, TRIM55, CRH, LINC00967, AC009879.4, RRS1-AS1, RRS1, AC009879.2, AC009879.3, ADHFE1, AC009879.1, VXN, RNU6-1324P.
- chr8:66,712,734–66,926,398, 5 genes, copy number 7: SGK3, PTTG3P, MCMDC2, SNHG6, SNORD87.
- chr8:67,173,511–67,407,072, 4 genes, copy number 7 (within-gene range 6–7): ARFGEF1, AC021321.2, AC021321.1, AC011037.1.
- chr8:68,848,737–69,178,189, 5 genes, copy number 7: AC083967.1, LINC01592, RNU7-102P, AF201337.1, AC021785.1.
- chr8:70,471,112–71,228,629, 12 genes, copy number 7: AC022730.3, AC022730.4, RN7SL203P, AC022730.1, TRAM1, LACTB2-AS1, LACTB2, RN7SL19P, XKR9, AC015687.1, Y_RNA, AC022858.1.
- chr8:74,320,613–74,518,007, 3 genes, copy number 7 (within-gene range 6–7): GDAP1, AC103952.1, Y_RNA.
- chr8:80,628,451–80,874,781, 4 genes, copy number 7 (within-gene range 6–7): ZNF704, CKS1BP7, RNU11-6P, RN7SL308P.
- chr8:86,866,415–87,874,015, 7 genes, copy number 7: CNBD1, AF121898.1, VTA1P2, IARS2P1, SOX5P1, AC005066.1, DCAF4L2.
- chr8:88,808,318–89,415,071, 3 genes, copy number 7: AC090578.2, RPSAP74, KRT8P4.
- chr8:89,900,721–90,687,863, 7 genes, copy number 7 (within-gene range 6–7): RNU6-925P, OSGIN2, NBN, DECR1, CALB1, AC004083.1, LINC00534.
- chr8:92,460,539–92,879,502, 5 genes, copy number 7 (within-gene range 6–7): AC091096.1, AC104211.1, FLJ46284, AC104211.2, AC117834.2.
- chr8:93,259,667–93,926,068, 16 genes, copy number 7 (within-gene range 6–7): AC016885.2, RNA5SP274, ZNF317P1, CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2.
- chr8:95,204,456–95,811,254, 6 genes, copy number 7 (within-gene range 6–7): C8orf37-AS1, LINC01298, C8orf37, AC024995.1, AC083836.1, RNU6-690P.
- chr8:100,427,559–100,559,784, 5 genes, copy number 7: AP003472.2, AP000424.1, AP000424.2, ANKRD46, GAPDHP62.
- chr8:101,261,541–101,307,428, 3 genes, copy number 7: LINC02844, AP001330.1, RNU7-67P.
- chr8:101,871,830–102,154,725, 3 genes, copy number 7: PDCL3P2, MIR5680, AP001328.1.
- chr8:102,551,589–103,073,051, 14 genes, copy number 7: ODF1, POU5F1P2, KLF10, ADI1P2, GASAL1, AZIN1, AP003696.1, MAILR, AP003354.1, RPL5P24, Y_RNA, NPM1P52, AP003550.1, ATP6V1C1.
- chr8:113,950,886–114,318,911, 3 genes, copy number 7: Y_RNA, AC064802.1, AC025881.1.
- chr8:117,794,490–118,982,875, 8 genes, copy number 7: EXT1, SAMD12, AC023590.1, SAMD12-AS1, RPS26P35, TNFRSF11B, RNU6-12P, AC107953.1.
- chr8:119,350,291–119,480,775, 5 genes, copy number 7: AC021733.4, AC021733.1, CCN3, AC021733.2, AC021733.3.
- chr8:122,779,971–123,470,028, 29 genes, copy number 7–8: AC016405.3, AC016405.2, ZHX2, AC016405.1, AC104316.2, AC104316.1, DERL1, TBC1D31, HMGB1P19, FAM83A, U3, AC068228.1, AC068228.2, FAM83A-AS1, MIR4663, C8orf76, ZHX1-C8orf76, UBA52P5, ZHX1, RNU6-628P, AC018992.1, ATAD2, RNU6-875P, MIR548AA1, MIR548D1, DUTP2, IMPDH1P6, NTAQ1, U4.
- chr8:125,430,358–126,292,788, 8 genes, copy number 7 (within-gene range 6–7): TRIB1, AC091114.1, AC016074.2, AC016074.1, LINC00861, RNU6-442P, SOD1P3, AC024681.2.
- chr8:126,174,186–126,558,478, 7 genes, copy number 7: RFPL4AP5, AC087667.1, AC084116.2, AC084116.1, RNU6-869P, AC084116.3, LRATD2.
- chr8:127,794,526–129,683,770, 15 genes, copy number 7 (within-gene range 6–7): PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226, LINC00824, CCDC26, AC103833.2.
- chr8:130,780,301–131,432,869, 6 genes, copy number 7: ADCY8, AC103726.1, AC103726.2, AC087341.1, AC104257.1, SNORA72.
- chr8:134,190,383–134,713,049, 8 genes, copy number 7: AC105180.2, AC105180.1, ZFAT, AC015599.1, ZFAT-AS1, AC015599.2, AC015599.3, AC087045.1.
- chr8:141,117,278–141,308,305, 7 genes, copy number 7: DENND3, AC040970.1, SLC45A4, AC011676.5, AC011676.1, AC011676.2, AC011676.3.
- chr20:21,947,647–64,327,972, 987 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 827. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
